Gene-level copy-number profile of tumor specimen TCGA-IG-A3I8-01A from TCGA case TCGA-IG-A3I8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,786 days).
Specimen TCGA-IG-A3I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ef6f42b8-756c-4653-b44b-7c8917915ebf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A3I8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64571980-7d81-4302-981a-113af732a7c5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 4,403; copy number 3: 17,615; copy number 4: 30,315; copy number 5: 295; copy number 6: 5,573; copy number 7: 59; copy number 8: 1,500; copy number 19: 16; copy number 42: 18; copy number 45: 6; copy number 55: 11; copy number 61: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A3I8-01A-11D-A246-01): tumor purity 0.62, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,481,662–70,398,488, 27 genes, copy number 19–55: LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:102,047,437–102,233,424, 6 genes, copy number 45: CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2.
- chr11:125,903,348–126,440,344, 24 genes, copy number 42–61 (within-gene range 4–61): DDX25, AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
